Gene-level copy-number profile of tumor specimen TCGA-BA-A6DA-01A from TCGA case TCGA-BA-A6DA, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Supraglottis; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 41.1 years (15,004 days).
Specimen TCGA-BA-A6DA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.f7ab305d-fb60-46f9-a1f6-6316a70bf7f0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BA-A6DA-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/39f58493-4505-46e9-a888-832a8d09fe33

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 8,318; copy number 2: 42,496; copy number 3: 4,912; copy number 4: 3,060; copy number 5: 785; copy number 6: 186; copy number 19: 52.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BA-A6DA-01A-31D-A31K-01): tumor purity 0.48, ploidy 2.14, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:12,098,660–12,159,148, 1 gene: AL589678.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,023 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:13,553,654–18,547,605, 94 genes, copy number 6 (broad region; genes not listed).
- chr8:95,204,456–95,811,254, 1 gene, copy number 5 (within-gene range 3–5): C8orf37-AS1.
- chr8:95,403,802–145,066,685, 784 genes, copy number 5 (broad region; genes not listed).
- chr11:68,870,664–70,436,584, 51 genes, copy number 19: LINC02701, MRPL21, IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:70,477,277–70,477,592, 1 gene, copy number 19: AP001271.1.
- chr14:21,941,128–22,524,381, 92 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6,210. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
